FM case AD97 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/e45b4595-29b1-4840-a70e-b3df1a8e7191

Male, 57.7 years: Adenoid cystic carcinoma (ICD-O-3 8200/3); specimen biopsied or resected from the eye. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
